Gene-level copy-number profile of tumor specimen TCGA-F1-A72C-01A from TCGA case TCGA-F1-A72C, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,104 days).
Specimen TCGA-F1-A72C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.da9179de-d34a-457c-b087-39c6c162766c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F1-A72C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c48882a7-6310-49ef-9494-62698e72234d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 15,383; copy number 2: 37,308; copy number 3: 7,006; copy number 4: 46; copy number 5: 59; copy number 6: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F1-A72C-01A-21D-A33S-01): tumor purity 0.39, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:178,116,721–178,406,830, 3 genes: RNU1-45P, AC095041.1, RNA5SP173.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,611,350–39,576,790, 59 genes, copy number 5: RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, LINC02786, AL390839.1, AL390839.2, LINC01343, AL513479.1, RNU6-753P, LINC01685, HSPA5P1, AL354702.1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55.
- chr6:15,994,944–16,295,549, 12 genes, copy number 6: LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1.

Autosomal genes at a single copy (total copy number 1): 12,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
